Somatic mutation profile of tumor specimen TCGA-AP-A051-01A (aliquot TCGA-AP-A051-01A-21W-A027-09) from TCGA case TCGA-AP-A051, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 69.2 years (25,269 days).
Specimen TCGA-AP-A051-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd4f0da1-5492-4cf2-b63b-9e27daf4f5a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A051-10A (Blood Derived Normal), aliquot TCGA-AP-A051-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d649e434-1a1b-4a2d-a25f-6a9a9c098a8d

The open-access MAF lists 10,048 somatic variants for this specimen: 7,593 protein-altering or splice-affecting, 2,251 silent, 204 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,543, Silent 2,251, Nonsense Mutation 420, Frame Shift Del 292, Splice Site 184, Intron 86, Splice Region 74, Frame Shift Ins 69, RNA 49, 3'UTR 29, 5'UTR 14, 5'Flank 13.

Variants (750 of 10,048; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, varscan2
- ADSL | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs763542069, CM068479, COSV53406726; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFG3L2 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1020764190, CM1511767, COSV52317569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGL | c.3911del p.N1304Ifs*10 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 34/124 reads (27%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APP | c.2140A>G p.T714A | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs63750643, CM021245, COSV61005117; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.4831C>T p.R1611* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | catalogued as rs1554236040, COSV51670259; ClinVar: pathogenic; called by muse, mutect2
- CASK | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 28/105 reads (27%) | catalogued as rs779508996, COSV59367508; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.4582C>T p.R1528C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs118204052, CM085310, COSV58012735; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKL5 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs122460159, CM081207, COSV66113460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD7 | c.5428C>T p.R1810* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs1554603552, CM060223, COSV71114014; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556418210, COSV60372485; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCX | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 201/660 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs104894784, CM980522, CM990468, COSV57572908; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.937+1G>A p.X313_splice | Splice Site (SNP) | VAF 79/221 reads (36%) | catalogued as rs201869739, CS024009, COSV50563997, COSV50598174; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 64/434 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852393, CM930211, COSV64278918; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1838-1G>A p.X613_splice | Splice Site (SNP) | VAF 54/183 reads (30%) | catalogued as rs1555399840, CS042163, CS161882, COSV57319905; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GHR | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 85/413 reads (21%) | catalogued as rs121909358, CM910179, COSV100049546; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD17B3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.351); catalogued as rs119481076, CM0910010, CM940951, COSV100931226; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IFT140 | c.3827G>A p.G1276E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779007169, CM1511472, COSV63699364; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IRAK4 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377584435, CM078314; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IRF6 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 24/136 reads (18%) | catalogued as rs121434224, CM022390, CM092335, COSV100884042, COSV65419096, COSV65419721; ClinVar: pathogenic; called by muse, varscan2
- KMT2A | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 43/177 reads (24%) | catalogued as rs1555037629, COSV63292691; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.*11G>A | 3'UTR (SNP) | VAF 19/88 reads (22%) | catalogued as rs1565878932, COSV56081012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LSM14A | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 39/150 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV70884731; called by muse, mutect2, varscan2
- MAF | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481963503, COSV58155265; ClinVar: likely pathogenic; called by muse, varscan2
- MYBPC3 | c.3811C>T p.R1271* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as rs397516042, CM086866, COSV57033880; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- NF1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 76/251 reads (30%) | hotspot (GDC flag); catalogued as rs878853865, CM000780, COSV62194747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PANK2 | c.1413-1G>T p.X471_splice (on ENST00000316562 / NM_153638.3; = p.X180_splice on NM_024960.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 25/104 reads (24%) | catalogued as rs148987163, CS033508; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLOD2 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as rs780770356, COSV51469342; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PMM2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746610168, CM051976, COSV51634507; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POGZ | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 47/305 reads (15%) | catalogued as rs1557901051, COSV55035225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRDM14 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 29/113 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762086448, COSV52571818; called by muse, mutect2, varscan2
- PTEN | c.548dup p.N184Efs*6 | Frame Shift Ins (INS) | VAF 176/358 reads (49%) | catalogued as rs1554900593, COSV64296770; ClinVar: pathogenic; called by pindel, varscan2
- RFT1 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749968109, CM1210536, COSV56249630; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN8A | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs796053233, COSV61993363; ClinVar: likely pathogenic; called by muse, varscan2
- SLC26A4 | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs111033454, CM165413; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SLC5A2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886037850, CM165643, COSV57891913; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TCOF1 | c.4365dup p.E1456Rfs*15 (on ENST00000377797 / NM_001135243.1; = p.E1379Rfs*15 on NM_000356.4) | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs587776585; ClinVar: pathogenic; called by mutect2, varscan2
- THAP1 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as rs1131691345, COSV54273817; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TNFRSF11B | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 58/188 reads (31%) | catalogued as rs1307942060, COSV52070601; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRNT1 | c.1252del p.S418Vfs*11 | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | catalogued as rs876661298, CM1411168, COSV51642664; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TTN | c.99592C>T p.R33198* (on ENST00000591111; = p.R25774* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 36/120 reads (30%) | catalogued as rs1553488049, COSV60194588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VDR | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909790, CM880063, COSV57470707; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 39/142 reads (27%) | catalogued as rs587784566, CM052018, COSV57966620; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 160/526 reads (30%) | catalogued as rs760319331, COSV51027342; called by mutect2, varscan2
- A2M | c.932T>C p.L311P | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV59392674; called by muse, mutect2, varscan2
- A2ML1 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs1267261235, COSV55284962; called by muse, mutect2
- AADAC | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV51761538; called by muse, varscan2
- AADACL3 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 128/413 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60200529; called by muse, mutect2, varscan2
- AAGAB | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406270299, COSV56018479; called by muse, varscan2
- AAK1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68646389, COSV68646556; called by muse, mutect2, varscan2
- AAMP | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1280087451, COSV50309743; called by muse, mutect2, varscan2
- AAR2 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.436); catalogued as rs1364398348, COSV57925016; called by muse, mutect2, varscan2
- AAR2 | c.892C>A p.L298I | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV57925025; called by muse, mutect2, varscan2
- AARS1 | c.671G>T p.R224M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55749646; called by muse, mutect2, varscan2
- AASS | c.2203A>G p.N735D | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV62791975; called by muse, mutect2, varscan2
- ABCA10 | c.2707G>T p.A903S | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV99073735; called by muse, mutect2
- ABCA13 | c.9042G>T p.K3014N | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as COSV71294858; called by muse, mutect2, varscan2
- ABCA13 | c.10736C>T p.T3579M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1388609306, COSV101446695, COSV71283618; called by muse, mutect2
- ABCA13 | c.13001C>A p.A4334D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV101291133; called by muse, mutect2, varscan2
- ABCA13 | c.14047C>T p.P4683S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV101291134; called by muse, mutect2
- ABCA13 | c.14270G>A p.G4757E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV68950901; called by muse, mutect2, varscan2
- ABCA4 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs764311517, COSV64678314; called by muse, mutect2, varscan2
- ABCA5 | c.4563G>T p.K1521N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67019163; called by muse, mutect2, varscan2
- ABCA6 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 94/362 reads (26%) | catalogued as COSV52645220; called by muse, mutect2, varscan2
- ABCA8 | c.4477C>A p.L1493M | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV52212719; called by muse, mutect2, varscan2
- ABCA9 | c.4190C>T p.A1397V | Missense Mutation (SNP) | VAF 102/349 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV60624058, COSV60631331; called by muse, mutect2, varscan2
- ABCB10 | c.2151G>T p.E717D | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV60624189; called by muse, mutect2, varscan2
- ABCB11 | c.2039G>A p.R680K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1443562207, COSV55601635; called by muse, mutect2, varscan2
- ABCB4 | c.3395G>A p.S1132N (on ENST00000265723 / NM_018849.3; = p.S1125N on NM_000443.4) | Missense Mutation (SNP) | VAF 87/345 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs199738630, COSV55942000; called by muse, mutect2, varscan2
- ABCB5 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51721056; called by muse, mutect2, varscan2
- ABCB7 | c.214G>T p.G72C (on ENST00000373394 / NM_001271696.3; = p.G73C on NM_004299.6) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as COSV53723971; called by muse, mutect2, varscan2
- ABCC11 | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1239984451, COSV62326000; called by muse, mutect2, varscan2
- ABCC11 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 36/164 reads (22%) | catalogued as rs543285690, COSV62326005; called by muse, mutect2, varscan2
- ABCC3 | c.2608G>T p.G870C | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV53329587; called by muse, mutect2, varscan2
- ABCC5 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV55596631; called by muse, mutect2, varscan2
- ABCC9 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 173/680 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV104370305, COSV53986914; called by muse, varscan2
- ABCD2 | c.2114C>A p.S705Y | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV58055852; called by muse, mutect2, varscan2
- ABCD2 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58055388; called by muse, mutect2, varscan2
- ABCD2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.549); catalogued as COSV58055398; called by muse, mutect2, varscan2
- ABCF2 | c.906A>C p.K302N | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV55186882; called by muse, varscan2
- ABCF2 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1421928370, COSV55183213; called by muse, mutect2, varscan2
- ABCG1 | c.1022T>C p.V341A | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV59210667; called by mutect2, varscan2
- ABCG5 | c.172A>C p.T58P | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53213617; called by muse, mutect2, varscan2
- ABHD12B | c.494G>A p.S165N (on ENST00000337334 / NM_001206673.2; = p.S88N on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs777753471, COSV61570955; called by muse, mutect2, varscan2
- ABHD17B | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 42/157 reads (27%) | catalogued as rs1197832194, COSV61009201; called by muse, mutect2, varscan2
- ABHD3 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56678621; called by muse, mutect2, varscan2
- ABHD5 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as COSV50007070, COSV99185486; called by muse, mutect2, varscan2
- ABL1 | c.3071G>A p.S1024N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.046); catalogued as COSV59341535; called by muse, mutect2, varscan2
- ABL2 | c.2764G>A p.V922I (on ENST00000502732 / NM_007314.4; = p.V907I on NM_005158.5) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs750153761, COSV100772276; called by mutect2, varscan2
- ABL2 | c.1114T>C p.Y372H (on ENST00000502732 / NM_007314.4; = p.Y357H on NM_005158.5) | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100772277; called by muse, mutect2
- ABT1 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51293206; called by muse, mutect2, varscan2
- AC005833.1 | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious, low confidence (0); catalogued as COSV99362347; called by muse, mutect2
- AC006059.2 | c.62T>C p.L21S | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV100359027; called by muse, mutect2
- AC013489.1 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51553892; called by muse, mutect2, varscan2
- AC092143.1 | c.2153G>A p.S718N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.977); catalogued as COSV59249237; called by muse, mutect2, varscan2
- AC098582.1 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867671166, COSV52024930; called by muse, mutect2, varscan2
- AC245033.1 | c.1350+1G>A p.X450_splice | Splice Site (SNP) | VAF 12/106 reads (11%) | catalogued as COSV55621623; called by muse, mutect2, varscan2
- ACACA | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as rs756880093; called by muse, mutect2, varscan2
- ACACB | c.5453G>A p.R1818Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs151300416; called by muse, mutect2, varscan2
- ACAD11 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 89/352 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV53901723; called by muse, mutect2, varscan2
- ACAD8 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs374584216, CM063823, COSV99844106; called by muse, mutect2, varscan2
- ACAP1 | c.1295G>T p.S432I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50141983, COSV50142331; called by muse, mutect2, varscan2
- ACAP2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV58753631; called by muse, mutect2, varscan2
- ACAT2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs906353564, COSV58460452; called by muse, varscan2
- ACCS | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs1449695415, COSV55460264; called by muse, varscan2
- ACD | c.1612G>T p.G538W (on ENST00000620338; = p.G449W on NM_022914.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV54670564; called by muse, mutect2, varscan2
- ACE | c.3131G>T p.S1044I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV52013307, COSV99326670; called by muse, mutect2, varscan2
- ACER3 | c.214+1G>A p.X72_splice | Splice Site (SNP) | VAF 73/176 reads (41%) | catalogued as COSV53603096; called by muse, mutect2, varscan2
- ACKR2 | c.461G>T p.R154M | Missense Mutation (SNP) | VAF 113/352 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV56180407; called by muse, mutect2, varscan2
- ACOT2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 32/121 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53151593; called by muse, mutect2, varscan2
- ACOT2 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV99468690; called by muse, mutect2, varscan2
- ACOT2 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as COSV53151599; called by muse, mutect2, varscan2
- ACOT4 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs1355356900, COSV58336383; called by muse, mutect2, varscan2
- ACOT6 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV66969045; called by muse, mutect2, varscan2
- ACOT7 | c.794A>G p.H265R (on ENST00000377855 / NM_181864.3; = p.H255R on NM_007274.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64115561; called by muse, mutect2, varscan2
- ACOX3 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs371422703, COSV100711833; called by muse, mutect2, varscan2
- ACP3 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs777524768, COSV60488700; called by muse, mutect2, varscan2
- ACP5 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV54537602; called by muse, mutect2, varscan2
- ACP5 | c.161T>C p.I54T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV54537623; called by muse, mutect2, varscan2
- ACSBG2 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV53127851; called by muse, mutect2, varscan2
- ACSBG2 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV53127860; called by muse, mutect2, varscan2
- ACSF2 | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs759600596, COSV51956396; called by muse, mutect2, varscan2
- ACSL1 | c.2091G>T p.K697N | Missense Mutation (SNP) | VAF 123/475 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55666625; called by muse, mutect2, varscan2
- ACSL1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as rs778163684, COSV55666636; called by muse, mutect2, varscan2
- ACSL5 | c.1197G>T p.K399N (on ENST00000354273; = p.K455N on NM_016234.3) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.481); catalogued as COSV100634397; called by mutect2, varscan2
- ACSM2A | c.1007C>A p.T336N (on ENST00000219054; = p.T257N on NM_001308169.2) | Missense Mutation (SNP) | VAF 119/382 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV54590031; called by muse, mutect2, varscan2
- ACSM2A | c.1460C>A p.A487D (on ENST00000219054; = p.A408D on NM_001308169.2) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54584269, COSV54590041; called by muse, mutect2, varscan2
- ACSM2A | c.1727C>T p.A576V (on ENST00000219054; = p.A497V on NM_001308169.2) | Missense Mutation (SNP) | VAF 120/358 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs141048019; called by mutect2, varscan2
- ACSM3 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs554041477, COSV55502192; called by muse, mutect2, varscan2
- ACSM4 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 28/507 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1183804854, COSV101256934; called by muse, mutect2
- ACSM4 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101256936, COSV68067055; called by mutect2, varscan2
- ACSS2 | c.248A>C p.N83T | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53628422; called by mutect2, varscan2
- ACSS2 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); catalogued as rs1202966100, COSV53628440; called by muse, mutect2, varscan2
- ACSS3 | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54101811; called by muse, mutect2, varscan2
- ACTA1 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV64204161; called by muse, varscan2
- ACTC1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.93); catalogued as rs876661340, CM1414558, COSV51761579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN1 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | catalogued as COSV51996747; called by muse, mutect2, varscan2
- ACTN2 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV63978402; called by muse, mutect2, varscan2
- ACTN2 | c.1812G>T p.M604I | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV63977157, COSV63978404; called by muse, mutect2, varscan2
- ACTN2 | c.2155-1G>A p.X719_splice | Splice Site (SNP) | VAF 39/198 reads (20%) | catalogued as COSV63978405; called by muse, varscan2
- ACTN3 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1565306080, COSV72207675; called by muse, mutect2, varscan2
- ACTN3 | c.1754T>C p.I585T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.662); catalogued as COSV59750625; called by muse, mutect2, varscan2
- ACVR1 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV55123058; called by muse, mutect2, varscan2
- ACVR1 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55123070; called by muse, varscan2
- ACVR1B | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV57780530; called by muse, mutect2, varscan2
- ACY3 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV54830301; called by muse, mutect2, varscan2
- ADAD1 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as rs370687144; called by muse, mutect2, varscan2
- ADAD1 | c.1649G>A p.C550Y | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.173); catalogued as rs752883123, COSV56647448; called by muse, mutect2, varscan2
- ADAL | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV67500167, COSV67501467; called by muse, mutect2, varscan2
- ADAM12 | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64107946, COSV64114963; called by muse, mutect2, varscan2
- ADAM15 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs780987112, COSV55127915; called by muse, mutect2, varscan2
- ADAM15 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as rs1035297613, COSV55129598; called by muse, mutect2, varscan2
- ADAM18 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs141094631; called by muse, mutect2, varscan2
- ADAM2 | c.1807A>G p.N603D | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV55868619; called by muse, mutect2, varscan2
- ADAM20 | c.414A>G p.I138M | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV56456701; called by muse, mutect2, varscan2
- ADAM23 | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV52230910; called by muse, mutect2, varscan2
- ADAM28 | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 19/178 reads (11%) | catalogued as COSV56105720; called by muse, mutect2
- ADAM29 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63668431, COSV63668954; called by muse, mutect2, varscan2
- ADAM29 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 103/608 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV63667450, COSV63668441; called by muse, mutect2, varscan2
- ADAM7 | c.1165T>C p.C389R | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1328605101, COSV51546856; called by muse, mutect2, varscan2
- ADAMTS10 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV54357422; called by muse, mutect2, varscan2
- ADAMTS12 | c.4319G>A p.G1440E | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61280579; called by muse, varscan2
- ADAMTS14 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100941243; called by muse, varscan2
- ADAMTS16 | c.1970G>T p.S657I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV57007611; called by muse, mutect2, varscan2
- ADAMTS16 | c.2765G>A p.C922Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57007624; called by muse, mutect2, varscan2
- ADAMTS16 | c.3233G>A p.C1078Y | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57007638; called by muse, mutect2, varscan2
- ADAMTS18 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV99270820; called by muse, mutect2
- ADAMTS18 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV99270823; called by muse, mutect2
- ADAMTS19 | c.3094G>A p.A1032T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs746700188, COSV50757439, COSV50788853, COSV50800289; called by muse, mutect2, varscan2
- ADAMTS20 | c.3740A>G p.D1247G | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67139706; called by muse, mutect2, varscan2
- ADAMTS20 | c.3515C>A p.T1172N | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV67139717; called by muse, mutect2, varscan2
- ADAMTS4 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.138); catalogued as COSV63488744; called by muse, mutect2, varscan2
- ADAMTS5 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs202109841, COSV53185636; called by muse, mutect2, varscan2
- ADAMTS9 | c.3469A>G p.T1157A | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.141); catalogued as COSV55791034; called by muse, mutect2, varscan2
- ADAMTSL3 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV104379388, COSV54470312; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4670G>A p.C1557Y | Missense Mutation (SNP) | VAF 94/331 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54470336; called by muse, mutect2, varscan2
- ADAR | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52720908, COSV52721380; called by muse, varscan2
- ADARB1 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs763381312, COSV62344527; called by muse, mutect2, varscan2
- ADARB2 | c.2177T>C p.V726A | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760933000, COSV101184511; called by mutect2, varscan2
- ADARB2 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV67237908; called by muse, mutect2, varscan2
- ADCY1 | c.899A>T p.D300V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV52040391; called by muse, mutect2, varscan2
- ADCY10 | c.4453G>A p.A1485T | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV63245054; called by muse, mutect2, varscan2
- ADCY10 | c.2635C>A p.L879I | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV100896473, COSV63245485; called by muse, mutect2
- ADCY10 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 159/780 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63245062; called by mutect2, varscan2
- ADCY2 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57901571; called by muse, mutect2, varscan2
- ADCY4 | c.3037G>A p.V1013M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs766567451, COSV60257807; called by mutect2, varscan2
- ADCY4 | c.2734-2A>G p.X912_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as COSV60257817; called by muse, mutect2, varscan2
- ADCY5 | c.1785G>T p.M595I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59204706; called by muse, mutect2, varscan2
- ADCY6 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57169643, COSV57170632; called by muse, mutect2, varscan2
- ADCY8 | c.2885A>G p.H962R | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53928648; called by muse, mutect2, varscan2
- ADD1 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV53274537; called by muse, mutect2, varscan2
- ADD3 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53326070; called by muse, mutect2, varscan2
- ADD3 | c.1322A>G p.N441S | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99523088; called by muse, mutect2
- ADGRB2 | c.3683C>T p.S1228F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57079105; called by muse, mutect2, varscan2
- ADGRB2 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57079113; called by muse, mutect2, varscan2
- ADGRB3 | c.1916C>A p.S639Y | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV65381797, COSV65420789; called by muse, varscan2
- ADGRB3 | c.2630C>A p.P877H | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53245001, COSV53265652, COSV99484969; called by muse, mutect2, varscan2
- ADGRB3 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV53259911; called by muse, mutect2
- ADGRB3 | c.4142G>A p.R1381H | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.976); catalogued as rs183570911, COSV53249297; called by muse, mutect2, varscan2
- ADGRD1 | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV55457900, COSV55460987; called by muse, varscan2
- ADGRD1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs746391447, COSV55446046; called by muse, mutect2, varscan2
- ADGRE1 | c.2612C>T p.T871I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs868493398, COSV99164983; called by muse, mutect2, varscan2
- ADGRE3 | c.1697G>A p.C566Y | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV53735066; called by muse, mutect2, varscan2
- ADGRF3 | c.3002C>A p.P1001H (on ENST00000311519 / NM_001145168.1; = p.P802H on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV61053458; called by muse, varscan2
- ADGRF3 | c.1993C>A p.L665I (on ENST00000311519 / NM_001145168.1; = p.L466I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.124); catalogued as rs1407343270, COSV61053473; called by muse, mutect2, varscan2
- ADGRG3 | c.1027dup p.A343Gfs*17 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | catalogued as rs764828465; called by mutect2, pindel, varscan2
- ADGRG4 | c.3227T>C p.V1076A | Missense Mutation (SNP) | VAF 587/1995 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54967102; called by muse, mutect2, varscan2
- ADGRG4 | c.3951G>T p.E1317D | Missense Mutation (SNP) | VAF 239/771 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1349230323, COSV54967115; called by muse, mutect2, varscan2
- ADGRG4 | c.6478C>A p.P2160T | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV54967121; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADGRG6 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs377682546; called by muse, mutect2, varscan2
- ADGRG6 | c.862A>G p.N288D | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs567514249, COSV99745467; called by muse, mutect2
- ADGRG7 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV99840387; called by muse, mutect2
- ADGRG7 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV56296155; called by muse, varscan2
- ADGRL2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 78/239 reads (33%) | catalogued as COSV54650641; called by muse, mutect2, varscan2
- ADGRL3 | c.331C>A p.L111I (on ENST00000506720 / NM_001322402.2; = p.L43I on NM_015236.6) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV72265739; called by muse, mutect2, varscan2
- ADGRL3 | c.737G>T p.R246I (on ENST00000506720 / NM_001322402.2; = p.R178I on NM_015236.6) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546862, COSV72273146; called by muse, mutect2, varscan2
- ADGRL3 | c.2089C>T p.R697C (on ENST00000506720 / NM_001322402.2; = p.R629C on NM_015236.6) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761017943, COSV72229893; called by muse, mutect2, varscan2
- ADGRL3 | c.3061G>A p.A1021T (on ENST00000506720 / NM_001322402.2; = p.A953T on NM_015236.6) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs765086852, COSV72231347, COSV72231995; called by muse, mutect2, varscan2
- ADGRV1 | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67982061, COSV67995771; called by muse, mutect2, varscan2
- ADGRV1 | c.5651C>T p.T1884I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.709); catalogued as COSV67995776; called by muse, mutect2, varscan2
- ADH1B | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.286); catalogued as COSV59298854; called by muse, mutect2, varscan2
- ADIPOR1 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61852506; called by muse, mutect2, varscan2
- ADM | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV53403872; called by muse, varscan2
- ADNP | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV62426921; called by muse, mutect2, varscan2
- ADNP | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV62425564; called by muse, mutect2, varscan2
- ADNP2 | c.701T>G p.I234S | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51542542; called by muse, mutect2, varscan2
- ADRB2 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs1209605702, COSV60005301; called by muse, mutect2, varscan2
- AEN | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV60430460; called by muse, mutect2, varscan2
- AFAP1L2 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV58418788; called by muse, mutect2, varscan2
- AFDN | c.4858C>T p.R1620C (on ENST00000447894 / NM_001366320.1; = p.R1618C on NM_001040000.3) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV60039779; called by muse, mutect2, varscan2
- AFF2 | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 87/693 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV60679777, COSV60682117; called by muse, mutect2, varscan2
- AFF2 | c.1328C>T p.T443I | Missense Mutation (SNP) | VAF 122/418 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV54008410; called by muse, mutect2, varscan2
- AFF3 | c.3593C>A p.P1198Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57874156; called by muse, mutect2, varscan2
- AFF3 | c.1603A>T p.T535S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV100417039; called by muse, mutect2
- AFF4 | c.3307T>G p.F1103V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); catalogued as COSV54800033; called by muse, mutect2, varscan2
- AFF4 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 55/174 reads (32%) | catalogued as COSV54800042; called by muse, mutect2, varscan2
- AFP | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1411506639, COSV56927214; called by muse, mutect2, varscan2
- AGA | c.394+1G>A p.X132_splice | Splice Site (SNP) | VAF 48/195 reads (25%) | catalogued as COSV52807694; called by muse, mutect2, varscan2
- AGAP1 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58339480; called by muse, mutect2, varscan2
- AGAP1 | c.721G>T p.G241* | Nonsense Mutation (SNP) | VAF 29/279 reads (10%) | catalogued as COSV58339487; called by muse, mutect2, varscan2
- AGAP3 | c.1708T>A p.S570T (on ENST00000622464; = p.S606T on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as COSV68246806; called by muse, mutect2, varscan2
- AGBL2 | c.1007T>C p.M336T | Missense Mutation (SNP) | VAF 89/336 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV54095570; called by muse, mutect2, varscan2
- AGBL5 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV59935871; called by muse, mutect2, varscan2
- AGL | c.3588+1G>A p.X1196_splice | Splice Site (SNP) | VAF 56/172 reads (33%) | catalogued as rs1397237820, COSV54059029; called by muse, mutect2, varscan2
- AGMO | c.1265T>A p.I422N | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV61124492; called by muse, varscan2
- AGMO | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as rs746980089, COSV61124504; called by muse, mutect2, varscan2
- AGO2 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1201563583, COSV55052922; called by muse, mutect2
- AGPAT5 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs765753866, COSV53449261; called by muse, mutect2, varscan2
- AGT | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs1334147335, COSV64183680; called by muse, mutect2, varscan2
- AGTR1 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62560266; called by muse, mutect2, varscan2
- AGTR2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV64157101; called by muse, mutect2, varscan2
- AGXT2 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.191); catalogued as COSV51490924; called by muse, varscan2
- AHCTF1 | c.5279C>G p.T1760S (on ENST00000366508; = p.T1734S on NM_015446.5) | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.121); catalogued as COSV58255934; called by muse, mutect2, varscan2
- AHCTF1 | c.4723C>A p.L1575I (on ENST00000366508; = p.L1549I on NM_015446.5) | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV58246441; called by muse, varscan2
- AHCTF1 | c.4252G>A p.A1418T (on ENST00000366508; = p.A1392T on NM_015446.5) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1446521303, COSV58255956; called by muse, mutect2, varscan2
- AHCYL1 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100779297; called by muse, mutect2
- AHI1 | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV55636372; called by muse, mutect2, varscan2
- AHI1 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs749254267, COSV55636406; called by muse, mutect2, varscan2
- AHNAK | c.15173C>T p.P5058L | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148778719; called by muse, mutect2, varscan2
- AHNAK | c.12580C>T p.P4194S | Missense Mutation (SNP) | VAF 122/462 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV57231205; called by muse, varscan2
- AHNAK | c.6727A>G p.M2243V | Missense Mutation (SNP) | VAF 54/463 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.721); catalogued as COSV57231219; called by muse, mutect2, varscan2
- AHNAK | c.3416T>A p.L1139H | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.632); catalogued as COSV57231231; called by muse, mutect2, varscan2
- AHNAK | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs369654662; called by muse, mutect2, varscan2
- AHNAK2 | c.16135G>T p.D5379Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60915147; called by muse, mutect2, varscan2
- AHNAK2 | c.7310T>C p.V2437A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV60931417; called by muse, mutect2, varscan2
- AHNAK2 | c.3402G>T p.E1134D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV60931421; called by mutect2, varscan2
- AHSA1 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs956397849, COSV53633251; called by muse, mutect2, varscan2
- AIFM3 | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV53151899; called by muse, mutect2, varscan2
- AIM2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1173989623, COSV100930996; called by muse, mutect2
- AK7 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50882636; called by muse, mutect2, varscan2
- AKAP11 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 129/410 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1239904915, COSV50302803; called by muse, mutect2, varscan2
- AKAP11 | c.1610del p.N537Ifs*8 | Frame Shift Del (DEL) | VAF 54/203 reads (27%) | catalogued as rs764225198; called by mutect2, pindel, varscan2
- AKAP11 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50302824; called by muse, mutect2, varscan2
- AKAP11 | c.4279A>T p.S1427C | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV50302863; called by muse, mutect2, varscan2
- AKAP13 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs990608403, COSV63464345; called by muse, mutect2, varscan2
- AKAP13 | c.5833T>C p.S1945P (on ENST00000394518 / NM_007200.5; = p.S1949P on NM_006738.6) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100772864; called by muse, mutect2
- AKAP13 | c.7433C>A p.A2478D (on ENST00000394518 / NM_007200.5; = p.A2482D on NM_006738.6) | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV63470414; called by muse, mutect2, varscan2
- AKAP14 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV57631441; called by muse, mutect2, varscan2
- AKAP3 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV57414186, COSV57420845; called by muse, mutect2, varscan2
- AKAP4 | c.2275G>A p.V759I | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV62075517; called by muse, mutect2, varscan2
- AKAP4 | c.1826C>A p.P609Q | Missense Mutation (SNP) | VAF 103/390 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.609); catalogued as COSV62075522; called by muse, mutect2, varscan2
- AKAP6 | c.4231C>T p.Q1411* | Nonsense Mutation (SNP) | VAF 65/213 reads (31%) | catalogued as COSV55234067; called by muse, mutect2, varscan2
- AKAP8 | c.21C>A p.G7= | Splice Region (SNP) | VAF 5/11 reads (45%) | catalogued as COSV54105034; called by muse, mutect2, varscan2
- AKAP9 | c.3644C>A p.T1215N | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV62358273; called by muse, mutect2, varscan2
- AKAP9 | c.5935C>T p.R1979C (on ENST00000359028; = p.R1947C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62337737; called by muse, mutect2, varscan2
- AKR1E2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV53631977; called by muse, mutect2, varscan2
- AKT2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs572670425, COSV60908440; called by muse, mutect2, varscan2
- AL136295.1 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55782086; called by muse, mutect2, varscan2
- AL592490.1 | c.2644G>T p.E882* | Nonsense Mutation (SNP) | VAF 36/114 reads (32%) | catalogued as COSV69427958, COSV69428014; called by muse, mutect2, varscan2
- AL592490.1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV69427963; called by muse, mutect2, varscan2
- AL645922.1 | c.2991G>A p.W997* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | catalogued as COSV100190495, COSV54960291; called by muse, mutect2
- ALAD | c.935C>A p.A312D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52960901; called by muse, mutect2, varscan2
- ALAS1 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 162/586 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59626671; called by mutect2, varscan2
- ALAS2 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.63); catalogued as COSV58193410; called by muse, mutect2, varscan2
- ALAS2 | c.1574G>T p.S525I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV58193432; called by muse, mutect2, varscan2
- ALDH1L2 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs143830632; called by muse, mutect2, varscan2
- ALDH2 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV55671476; called by muse, mutect2, varscan2
- ALDH3A2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as rs779945294, COSV51566168; called by muse, mutect2, varscan2
- ALDH3B1 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs200028780; called by muse, mutect2, varscan2
- ALDH3B1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV99141644; called by muse, mutect2, varscan2
- ALDH5A1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773814880, COSV62373402, COSV62374578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG13 | c.3038T>C p.V1013A | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757875463, COSV52645168; called by muse, mutect2, varscan2
- ALG6 | c.902G>T p.S301I | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV54767948; called by muse, mutect2, varscan2
- ALK | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1442742511, COSV66580377; called by muse, mutect2, varscan2
- ALKBH3 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV57026622; called by muse, mutect2, varscan2
- ALKBH4 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs371943941; called by muse, mutect2, varscan2
- ALMS1 | c.7322A>T p.D2441V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52522440; called by muse, mutect2, varscan2
- ALMS1 | c.9781+1G>T p.X3261_splice | Splice Site (SNP) | VAF 54/324 reads (17%) | catalogued as COSV52522446; called by muse, mutect2, varscan2
- ALOX15 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.087); catalogued as rs752703451, COSV53400863; called by mutect2, varscan2
- ALOXE3 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs375389989; called by muse, mutect2, varscan2
- ALPK2 | c.5738G>A p.R1913H | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs778586800, COSV64497362; called by muse, mutect2, varscan2
- ALPK2 | c.4333G>T p.A1445S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV64497370; called by muse, mutect2, varscan2
- ALPK3 | c.1454C>A p.P485H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs751233026, COSV51940003; called by muse, mutect2, varscan2
- ALPK3 | c.3927G>A p.W1309* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99359988; called by muse, mutect2
- ALPK3 | c.4052A>G p.E1351G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51940034; called by muse, varscan2
- ALPL | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as COSV66380862; called by muse, mutect2, varscan2
- ALS2 | c.4558C>A p.L1520M | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.925); catalogued as COSV51892755; called by muse, mutect2, varscan2
- ALS2 | c.3026G>T p.R1009I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV51892768, COSV51894007; called by muse, varscan2
- ALS2 | c.2110C>T p.R704* | Nonsense Mutation (SNP) | VAF 52/166 reads (31%) | catalogued as rs748568886, COSV51892777; called by muse, mutect2, varscan2
- AMBN | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV59828193; called by muse, mutect2, varscan2
- AMER1 | c.1459C>A p.L487M | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100365113; called by muse, mutect2
- AMER2 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.111); catalogued as COSV63437199; called by muse, varscan2
- AMER3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs760037550, COSV58470422; called by muse, mutect2, varscan2
- AMOT | c.1825G>A p.A609T (on ENST00000371959 / NM_001113490.1; = p.A200T on NM_133265.3) | Missense Mutation (SNP) | VAF 89/348 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59068723; called by muse, mutect2, varscan2
- AMPD1 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62417658, COSV62419149; called by muse, varscan2
- AMPD3 | c.178C>T p.Q60* (on ENST00000396553 / NM_001025389.2; = p.Q69* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV67332482; called by muse, mutect2, varscan2
- AMPD3 | c.2267C>A p.A756D (on ENST00000396553 / NM_001025389.2; = p.A765D on NM_000480.3) | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV67332491; called by muse, mutect2, varscan2
- ANAPC4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs755236879, COSV59546370; called by muse, mutect2, varscan2
- ANGEL2 | c.1571T>A p.L524H | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64738355; called by muse, mutect2, varscan2
- ANGPTL1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as COSV52368228; called by muse, mutect2, varscan2
- ANK2 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52144257; called by muse, mutect2, varscan2
- ANK2 | c.8041C>A p.L2681I | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52189540; called by muse, mutect2, varscan2
- ANK2 | c.10975C>T p.R3659C | Missense Mutation (SNP) | VAF 27/275 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs370699621; ClinVar: uncertain significance; called by muse, mutect2
- ANK3 | c.11785G>A p.A3929T | Missense Mutation (SNP) | VAF 130/440 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV55082804; called by muse, mutect2, varscan2
- ANK3 | c.9160T>G p.F3054V | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV55082817; called by muse, mutect2, varscan2
- ANK3 | c.2675T>C p.L892S (on ENST00000280772 / NM_001320874.2; = p.L26S on NM_001149.3) | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55060880; called by muse, mutect2, varscan2
- ANK3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs748812113, COSV55056871; called by mutect2, varscan2
- ANKEF1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs377375975; called by muse, mutect2, varscan2
- ANKEF1 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 42/144 reads (29%) | catalogued as COSV65693784; called by muse, mutect2, varscan2
- ANKFN1 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757619098, COSV59442842; called by muse, mutect2, varscan2
- ANKFY1 | c.1616A>T p.D539V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58923198; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.5684C>A p.P1895H | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV51859006; called by muse, mutect2, varscan2
- ANKIB1 | c.1792T>G p.F598V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99728073; called by muse, mutect2
- ANKIB1 | c.2605C>A p.L869M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.03); catalogued as COSV56066336; called by muse, mutect2, varscan2
- ANKK1 | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV58274355; called by muse, mutect2, varscan2
- ANKLE1 | c.932C>T p.A311V (on ENST00000394458; = p.A257V on NM_152363.6) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV63921653; called by muse, mutect2, varscan2
- ANKLE1 | c.1792G>A p.A598T (on ENST00000394458; = p.A544T on NM_152363.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs547043530, COSV101081978; called by muse, varscan2
- ANKRD1 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV65468474; called by muse, mutect2, varscan2
- ANKRD11 | c.4871C>T p.A1624V | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56372411; called by muse, mutect2, varscan2
- ANKRD13C | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52035317; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.44); catalogued as rs1449537291; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1692G>T p.E564D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV62007967; called by mutect2, varscan2
- ANKRD26 | c.2769G>A p.M923I | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs1447667481, COSV65778477; called by muse, mutect2, varscan2
- ANKRD28 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV67520209; called by muse, mutect2, varscan2
- ANKRD30A | c.1572+1G>T p.X524_splice (on ENST00000611781; = p.X468_splice on NM_052997.2) | Splice Site (SNP) | VAF 72/298 reads (24%) | catalogued as COSV64608073; called by muse, mutect2, varscan2
- ANKRD30A | c.2037C>A p.D679E (on ENST00000611781; = p.D623E on NM_052997.2) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.785); catalogued as COSV64609473; called by muse, mutect2, varscan2
- ANKRD36B | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); catalogued as COSV51537202; called by muse, mutect2, varscan2
- ANKRD44 | c.2566C>T p.Q856* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as COSV99983754; called by muse, mutect2
- ANKRD44 | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56566610; called by muse, mutect2, varscan2
- ANKRD45 | c.459T>G p.Y153* | Nonsense Mutation (SNP) | VAF 68/429 reads (16%) | catalogued as COSV60962643; called by muse, mutect2, varscan2
- ANKRD50 | c.1621T>C p.C541R | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV72386336; called by muse, mutect2, varscan2
- ANKRD50 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV101538862; called by muse, mutect2
- ANKZF1 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs747660271, COSV55479134; called by muse, mutect2, varscan2
- ANO1 | c.1808A>G p.E603G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60289508; called by muse, mutect2, varscan2
- ANO2 | c.1807C>A p.L603I (on ENST00000356134 / NM_001278597.3; = p.L607I on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.587); catalogued as COSV59043902; called by muse, mutect2, varscan2
- ANO5 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV61090419; called by muse, mutect2, varscan2
- ANO5 | c.1375T>C p.Y459H | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV100201268; called by muse, mutect2
- ANO5 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61084618; called by muse, mutect2, varscan2
- ANO6 | c.2383A>G p.N795D | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV100261968; called by muse, mutect2
- ANO7 | c.1733G>A p.R578H (on ENST00000274979; = p.R524H on NM_001370694.2) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs778300142, COSV51468501, COSV51469706; called by muse, mutect2, varscan2
- ANO8 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50199648; called by muse, mutect2, varscan2
- ANO9 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as rs780486405, COSV60385445; called by mutect2, varscan2
- ANP32E | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV58481327; called by muse, mutect2, varscan2
- ANPEP | c.2764A>G p.K922E | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV55595420; called by muse, mutect2, varscan2
- ANTXR2 | c.1241C>A p.A414D | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56320052; called by muse, mutect2, varscan2
- ANXA1 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs746783076, COSV57412807; called by muse, mutect2, varscan2
- ANXA13 | c.528A>C p.K176N | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV51626811; called by muse, mutect2, varscan2
- ANXA2 | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60318827; called by muse, mutect2, varscan2
- ANXA6 | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62908475; called by muse, mutect2, varscan2
- ANXA8 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1284603752; called by muse, mutect2, varscan2
- AOC2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs142697203; called by muse, mutect2, varscan2
- AOC3 | c.17T>C p.I6T | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53828883; called by muse, mutect2, varscan2
- AOC3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs766793528, COSV53828577; called by muse, mutect2, varscan2
- AOC3 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as rs573304904, COSV53825277; called by muse, mutect2, varscan2
- AOPEP | c.1873-1G>A p.X625_splice (on ENST00000375315 / NM_001193329.1; = p.X526_splice on NM_032823.5) | Splice Site (SNP) | VAF 17/132 reads (13%) | catalogued as COSV52999308; called by muse, mutect2, varscan2
- AOX1 | c.2275C>A p.L759I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.377); catalogued as COSV65984223; called by muse, mutect2, varscan2
- AP002748.5 | c.1388A>T p.N463I | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as COSV59151881, COSV59152058; called by muse, mutect2, varscan2
- AP1AR | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs746515200, COSV56769250, COSV99914166; called by muse, mutect2, varscan2
- AP1S1 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255603930, COSV61760928, COSV61760936; called by muse, mutect2, varscan2
- AP2A1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1401108451, COSV62821140; called by muse, mutect2, varscan2
- AP2A1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447484112, COSV62821149; called by muse, varscan2
- AP2B1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52003591; called by muse, mutect2, varscan2
- AP3M2 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99441256; called by muse, mutect2
- AP4B1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763842373, COSV56725261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP4E1 | c.2827G>A p.V943I | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV55920295; called by muse, mutect2, varscan2
- APAF1 | c.1939G>T p.G647* (on ENST00000551964 / NM_181861.2; = p.G636* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV59668675; called by muse, mutect2, varscan2
- APBA2 | c.776A>G p.E259G | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV68795610; called by muse, mutect2, varscan2
- APBB1IP | c.632C>A p.T211N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.74); catalogued as COSV63076710; called by muse, mutect2, varscan2
- APBB3 | c.1022A>G p.H341R (on ENST00000357560 / NM_133173.2; = p.H348R on NM_006051.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV60054466; called by muse, mutect2, varscan2
- APBB3 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV60054472; called by muse, mutect2, varscan2
- APC | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV57383927, COSV57388442; called by muse, mutect2, varscan2
- APC | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57383935; called by muse, mutect2, varscan2
- APC | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1165139414, COSV57328964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEH | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99610467; called by muse, mutect2
- APLF | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100376244; called by muse, mutect2
- APLP1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs781164817, COSV55707026; called by muse, varscan2
- APLP1 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV55705532; called by muse, varscan2
- APLP2 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs758370829, COSV53844833; called by muse, mutect2, varscan2
- APLP2 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs536665333, COSV53843723; called by muse, varscan2
- APOB | c.9386C>T p.P3129L | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV51940315, COSV51952981, COSV51954087; called by muse, varscan2
- APOB | c.8443T>A p.S2815T | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.16); catalogued as COSV51953000; called by muse, varscan2
- APOB | c.7610C>A p.S2537Y | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV51936053, COSV51953009; called by muse, mutect2, varscan2
- APOB | c.6295C>A p.L2099M | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs372799407, COSV51953018; called by muse, mutect2, varscan2
- APOB | c.3725C>A p.S1242Y | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV51946878; called by muse, mutect2, varscan2
- APOB | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV51953259; called by muse, mutect2, varscan2
- APOB | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 32/129 reads (25%) | catalogued as COSV51953270; called by muse, varscan2
- APOB | c.1655C>A p.A552D | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.576); catalogued as rs765746519, COSV51953279; called by muse, varscan2
- APOBEC2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99775271; called by muse, mutect2
- APOBEC3B | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.457); catalogued as rs781129393, COSV59842034; called by mutect2, varscan2
- APOBEC3D | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs375389371; called by muse, mutect2, varscan2
- APOBEC3D | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV53328830, COSV99329136; called by muse, mutect2, varscan2
- APOBEC3F | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100415077; called by muse, mutect2, varscan2
- APOF | c.947A>C p.D316A | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV58477521; called by muse, mutect2, varscan2
- APOF | c.657A>G p.I219M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.803); catalogued as COSV58477526; called by muse, varscan2
- APOF | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV58477529; called by muse, varscan2
- APOL2 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV50772497; called by muse, mutect2, varscan2
- APP | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 91/302 reads (30%) | catalogued as COSV61005122; called by mutect2, varscan2
- APP | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV100695157; called by muse, mutect2
- APPBP2 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99319370; called by muse, mutect2
- APPBP2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs773488287, COSV50029717; called by muse, mutect2, varscan2
- APPL2 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs779187749, COSV51593915; called by muse, mutect2, varscan2
- APTX | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs367998288; called by muse, mutect2, varscan2
- AQP10 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs761850160, COSV61475084; called by muse, varscan2
- AQP5 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs748231984, COSV53311959; called by muse, mutect2, varscan2
- AQP8 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as COSV54844103; called by muse, mutect2, varscan2
- ARAP3 | c.1109G>A p.W370* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV53355055; called by muse, mutect2, varscan2
- ARAP3 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.581); catalogued as COSV53354054; called by muse, mutect2, varscan2
- ARCN1 | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50617723; called by muse, mutect2, varscan2
- ARF1 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV55256038; called by muse, mutect2, varscan2
- ARFGAP2 | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV60302301; called by muse, mutect2, varscan2
- ARFGEF1 | c.4967C>T p.A1656V | Missense Mutation (SNP) | VAF 33/348 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs771740489, COSV51607453; called by muse, mutect2
- ARFGEF2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs778834589, COSV64211088; ClinVar: uncertain significance; called by mutect2, varscan2
- ARFGEF2 | c.1658C>A p.P553H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV64215264; called by muse, mutect2, varscan2
- ARFGEF2 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100904260, COSV64211074; called by muse, mutect2, varscan2
- ARFGEF2 | c.2104A>T p.R702W | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100903923; called by muse, mutect2
- ARFGEF2 | c.3121G>A p.G1041S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs537313958, COSV64215270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF2 | c.3809C>A p.A1270D | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs757491379, COSV64215273; called by muse, mutect2, varscan2
- ARFGEF3 | c.2968G>A p.V990I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs773124641, COSV52471408; called by mutect2, varscan2
- ARFGEF3 | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs770178501, COSV99292015; called by muse, mutect2
- ARFGEF3 | c.6082G>T p.E2028* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV52471424; called by mutect2, varscan2
- ARFIP1 | c.812G>A p.R271H (on ENST00000353617 / NM_001287432.1; = p.R239H on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs972103124, COSV61883329; called by muse, mutect2, varscan2
- ARFIP1 | c.922C>T p.R308C (on ENST00000353617 / NM_001287432.1; = p.R276C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367792760; called by muse, mutect2, varscan2
- ARHGAP12 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 156/479 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs755977039, COSV60963576; called by muse, mutect2, varscan2
- ARHGAP15 | c.1196C>A p.P399H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54522085; called by muse, mutect2, varscan2
- ARHGAP19 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV57391470; called by muse, mutect2, varscan2
- ARHGAP22 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1256478688, COSV50988816; called by muse, mutect2, varscan2
- ARHGAP24 | c.2183C>T p.T728M (on ENST00000395184 / NM_001025616.3; = p.T635M on NM_031305.3) | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775711657, COSV51993862; called by mutect2, varscan2
- ARHGAP27 | c.1231C>A p.H411N (on ENST00000428638 / NM_001282290.1; = p.H70N on NM_199282.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs865948265; called by muse, mutect2
- ARHGAP29 | c.3535A>G p.N1179D | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV53107946; called by muse, mutect2, varscan2
- ARHGAP29 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs144191284; called by muse, mutect2, varscan2
- ARHGAP30 | c.3007C>A p.L1003I (on ENST00000368013 / NM_001025598.2; = p.L792I on NM_181720.3) | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); catalogued as COSV63519591; called by muse, mutect2, varscan2
- ARHGAP30 | c.2909G>A p.R970Q (on ENST00000368013 / NM_001025598.2; = p.R759Q on NM_181720.3) | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as rs780720572, COSV63517792; called by muse, mutect2, varscan2
- ARHGAP30 | c.2768G>A p.R923H (on ENST00000368013 / NM_001025598.2; = p.R712H on NM_181720.3) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748205506, COSV63519608; called by muse, mutect2, varscan2
- ARHGAP31 | c.3637C>T p.P1213S | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51799411; called by muse, mutect2, varscan2
- ARHGAP32 | c.3821G>A p.S1274N (on ENST00000310343 / NM_001378025.1; = p.S925N on NM_014715.4) | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV59855939; called by muse, mutect2, varscan2
- ARHGAP32 | c.3227C>T p.A1076V (on ENST00000310343 / NM_001378025.1; = p.A727V on NM_014715.4) | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.122); catalogued as rs376432253; called by muse, mutect2, varscan2
- ARHGAP32 | c.2990G>A p.S997N (on ENST00000310343 / NM_001378025.1; = p.S648N on NM_014715.4) | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV59855961; called by muse, mutect2, varscan2
- ARHGAP32 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.943); catalogued as rs750991097, COSV59852040; called by mutect2, varscan2
- ARHGAP35 | c.3184G>T p.G1062C | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV68331878, COSV68335792; called by muse, mutect2, varscan2
- ARHGAP36 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV52263795; called by muse, mutect2, varscan2
- ARHGAP44 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52403112; called by muse, mutect2, varscan2
- ARHGAP5 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.397); catalogued as COSV61539359; called by muse, mutect2, varscan2
- ARHGAP5 | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV61539363; called by muse, mutect2, varscan2
- ARHGAP9 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs770739425, COSV62724519; called by muse, mutect2, varscan2
- ARHGDIB | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV56764827; called by muse, mutect2, varscan2
- ARHGEF1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369826806, COSV61526868; called by muse, mutect2, varscan2
- ARHGEF10 | c.1397C>T p.T466M (on ENST00000398564; = p.T441M on NM_014629.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs146529284; called by muse, mutect2, varscan2
- ARHGEF10 | c.2042G>A p.R681H (on ENST00000398564; = p.R656H on NM_014629.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs184791801; called by muse, mutect2, varscan2
- ARHGEF10 | c.2828C>A p.S943Y (on ENST00000398564; = p.S918Y on NM_014629.4) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1251397301, COSV50679317; called by mutect2, varscan2
- ARHGEF10L | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV51440820; called by muse, mutect2, varscan2
- ARHGEF11 | c.3559G>A p.A1187T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.135); catalogued as COSV59358804; called by muse, mutect2, varscan2
- ARHGEF11 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1420230862, COSV59356893; called by muse, mutect2, varscan2
- ARHGEF11 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV59358839; called by muse, mutect2, varscan2
- ARHGEF11 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs768597800, COSV63810625; called by muse, mutect2
- ARHGEF12 | c.3363T>G p.T1121= | Splice Region (SNP) | VAF 24/119 reads (20%) | catalogued as COSV63107420; called by muse, mutect2, varscan2
- ARHGEF12 | c.3364G>A p.V1122I | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs776281342, COSV63107423; called by muse, mutect2, varscan2
- ARHGEF15 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs375713883; called by mutect2, varscan2
- ARHGEF17 | c.1469C>A p.P490H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.254); catalogued as COSV55238417; called by muse, mutect2, varscan2
- ARHGEF4 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as rs746676393, COSV58130389; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs749402223; called by pindel, varscan2
- ARHGEF5 | c.3908G>A p.R1303H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1347124810, COSV50219570; called by mutect2, varscan2
- ARHGEF9 | c.1045C>A p.L349I | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.15); catalogued as rs483352738, COSV53644642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF9 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53644671; called by muse, mutect2, varscan2
- ARID1A | c.5568G>T p.Q1856H | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61389461; called by muse, varscan2
- ARID3A | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55046614; called by muse, mutect2, varscan2
- ARID4B | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 93/482 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs144849243; called by muse, mutect2, varscan2
- ARL14 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57900501; called by muse, mutect2, varscan2
- ARL6IP6 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58444577; called by muse, mutect2, varscan2
- ARL8A | c.540C>A p.H180Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV55344218; called by muse, mutect2, varscan2
- ARMC1 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52534888; called by muse, mutect2, varscan2
- ARMC10 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60393408; called by muse, mutect2, varscan2
- ARMC12 | c.769C>T p.R257W (on ENST00000373866 / NM_001286574.2; = p.R284W on NM_145028.5) | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs147643446; called by muse, varscan2
- ARMC4 | c.1550T>C p.I517T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs922103777, COSV59474324; called by muse, varscan2
- ARMC8 | c.1201C>T p.R401W (on ENST00000469044 / NM_001363941.2; = p.R387W on NM_015396.6) | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1307854914, COSV58620603; called by muse, mutect2, varscan2
- ARMC9 | c.1915C>A p.L639M | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV63023817; called by muse, varscan2
- ARMCX2 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs782086194, COSV100168087, COSV57531153; called by muse, mutect2, varscan2
- ARMCX3 | c.572G>T p.S191I | Missense Mutation (SNP) | VAF 75/329 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57871704; called by muse, mutect2, varscan2
- ARMCX5 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 81/489 reads (17%) | catalogued as COSV55767691; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 86/649 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63437139; called by muse, mutect2, varscan2
- ARMCX6 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781804370, COSV62680969; called by muse, mutect2, varscan2
- ARMH3 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.018); catalogued as rs776115367, COSV64238244; called by muse, mutect2, varscan2
- ARMH4 | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50774422; called by muse, mutect2, varscan2
- ARNTL | c.1046A>C p.K349T (on ENST00000403290 / NM_001297719.2; = p.K348T on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100724488; called by muse, mutect2
- ARPC3 | c.197G>T p.R66M | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57400600; called by muse, mutect2, varscan2
- ARPIN | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs370605817; called by muse, mutect2, varscan2
- ARPP21 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV51808603; called by muse, mutect2, varscan2
- ARRDC3 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as rs777796833, COSV54364590; called by muse, mutect2, varscan2
- ARRDC3 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs1372725760, COSV54365359; called by muse, mutect2, varscan2
- ARSB | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53729566; called by muse, mutect2, varscan2
- ARSD | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as rs1398491250, COSV54203291; called by muse, mutect2, varscan2
- ARSD | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV54203299; called by muse, mutect2, varscan2
- ARSL | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV66965978; called by mutect2, varscan2
- ARSL | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV66965991; called by muse, mutect2, varscan2
- ASAP1 | c.2767A>G p.K923E | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.708); catalogued as COSV100726743; called by muse, mutect2
- ASAP3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs759918483, COSV60878155; called by mutect2, varscan2
- ASB11 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV60356674; called by muse, mutect2, varscan2
- ASB12 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.263); catalogued as rs754029861, COSV62857787; called by muse, mutect2, varscan2
- ASB15 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as COSV51929462, COSV99306536; called by muse, mutect2, varscan2
- ASB17 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs770024127, COSV52412210; called by muse, mutect2, varscan2
- ASCC1 | c.566G>A p.C189Y (on ENST00000342444 / NM_001369085.1; = p.C161Y on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.615); catalogued as COSV57729117; called by muse, mutect2, varscan2
- ASCC3 | c.4679T>G p.I1560R | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV64981350; called by muse, mutect2, varscan2
- ASCC3 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV61233929; called by muse, mutect2, varscan2
- ASCL1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57152675; called by muse, mutect2, varscan2
- ASCL3 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.947); catalogued as COSV57942220; called by muse, mutect2, varscan2
- ASGR2 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54691628; called by muse, mutect2, varscan2
- ASH1L | c.8515C>T p.R2839* (on ENST00000368346 / NM_001366177.2; = p.R2834* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 77/207 reads (37%) | catalogued as COSV64206891; called by muse, mutect2, varscan2
- ASH1L | c.5293C>A p.L1765I | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV64214022; called by muse, mutect2, varscan2
- ASPA | c.930C>A p.C310* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV53982863; called by muse, mutect2, varscan2
- ASPH | c.2054G>A p.C685Y | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65247713; called by muse, mutect2, varscan2
- ASPHD2 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.286); catalogued as COSV53220936; called by muse, mutect2, varscan2
- ASPM | c.9984+2T>C p.X3328_splice | Splice Site (SNP) | VAF 70/445 reads (16%) | catalogued as COSV54138965; called by muse, varscan2
- ASPM | c.9866A>C p.N3289T | Missense Mutation (SNP) | VAF 52/538 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99659253; called by muse, mutect2
- ASPM | c.9638C>T p.A3213V | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54138971; called by muse, mutect2, varscan2
- ASPM | c.9541C>T p.R3181* | Nonsense Mutation (SNP) | VAF 86/386 reads (22%) | catalogued as rs754689827, COSV54138985; called by muse, mutect2, varscan2
- ASPM | c.9355C>A p.L3119M | Missense Mutation (SNP) | VAF 66/397 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV54138997; called by muse, mutect2, varscan2
- ASPM | c.5000G>A p.R1667H | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754282386, COSV54128526, COSV54139009; ClinVar: uncertain significance; called by muse, varscan2
- ASPM | c.4953G>A p.M1651I | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.636); catalogued as rs1238789233, COSV54139021; called by muse, varscan2
- ASPM | c.626A>C p.N209T | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54139031; called by muse, mutect2, varscan2
- ASPRV1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs963601402, COSV57228295; called by muse, mutect2, varscan2
- ASTN1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs750249282, COSV56061957, COSV56086029; called by muse, mutect2, varscan2
- ASTN2 | c.1898C>T p.A633V (on ENST00000313400 / NM_001365069.1; = p.A582V on NM_014010.5) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs752461666, COSV57818498; called by muse, mutect2, varscan2
- ASTN2 | c.1423G>T p.G475* (on ENST00000313400 / NM_001365069.1; = p.G424* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100523570; called by muse, mutect2, varscan2
- ASXL1 | c.3737T>A p.V1246D | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV60122558; called by muse, mutect2, varscan2
- ASXL2 | c.2675C>T p.T892I | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV55468189; called by muse, mutect2, varscan2
- ASXL3 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV52468081; called by muse, varscan2
- ASXL3 | c.6170C>A p.P2057H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99322799, COSV99325871; called by muse, mutect2
- ATAD5 | c.2837T>G p.L946R | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as rs1322998233, COSV58979464; called by muse, mutect2, varscan2
- ATAD5 | c.4376C>A p.A1459D | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV58979473; called by muse, mutect2, varscan2
- ATE1 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs760706352, COSV56443443; called by muse, mutect2, varscan2
- ATF6 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 182/927 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63410245; called by muse, mutect2, varscan2
- ATF6 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 61/301 reads (20%) | catalogued as rs746887984, CM155686, COSV63410248; called by muse, mutect2, varscan2
- ATF6 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 33/185 reads (18%) | catalogued as COSV63410251; called by muse, mutect2, varscan2
- ATF6 | c.1640C>A p.A547D | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100908971; called by muse, mutect2
- ATF7IP | c.2878G>T p.G960C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV53767223, COSV53778249; called by muse, mutect2, varscan2
- ATG13 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV56322195; called by muse, mutect2, varscan2
- ATG14 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs371708306, COSV55958279; called by muse, mutect2, varscan2
- ATG16L1 | c.946T>C p.C316R (on ENST00000392017 / NM_030803.7; = p.C297R on NM_017974.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as COSV61468161; called by muse, mutect2, varscan2
- ATG16L1 | c.1745C>T p.A582V (on ENST00000392017 / NM_030803.7; = p.A563V on NM_017974.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1471623952, COSV61465548, COSV61465600; called by muse, mutect2, varscan2
- ATG2B | c.1224C>A p.F408L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV63425744; called by muse, mutect2, varscan2
- ATG3 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as rs758218316, COSV51928601; called by muse, mutect2, varscan2
- ATG4A | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV58967591; called by muse, mutect2, varscan2
- ATIC | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV52695404; called by muse, mutect2, varscan2
- ATL1 | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV63297780; called by muse, mutect2, varscan2
- ATM | c.2156C>A p.S719* | Nonsense Mutation (SNP) | VAF 41/110 reads (37%) | catalogued as COSV53776072; called by muse, mutect2, varscan2
- ATN1 | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV63110820, COSV63113112; called by muse, varscan2
- ATN1 | c.1051A>C p.T351P | Missense Mutation (SNP) | VAF 119/396 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV63113119; called by muse, varscan2
- ATP10A | c.4435C>T p.R1479* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as rs1051708992, COSV63518302; called by muse, mutect2, varscan2
- ATP10B | c.3476C>A p.P1159H | Missense Mutation (SNP) | VAF 191/631 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59165034; called by muse, mutect2, varscan2
- ATP10B | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762149091, COSV59164051; called by muse, mutect2, varscan2
- ATP10D | c.1499G>T p.S500I | Missense Mutation (SNP) | VAF 55/387 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as COSV56713280; called by muse, mutect2, varscan2
- ATP10D | c.1898C>A p.S633Y | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56713287; called by muse, mutect2, varscan2
- ATP11A | c.2779C>T p.L927F | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.408); catalogued as COSV52119711; called by muse, mutect2, varscan2
- ATP11B | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as rs1237389093, COSV60033534; called by muse, mutect2, varscan2
- ATP11C | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs1569462672, COSV100557138; called by muse, mutect2
- ATP13A4 | c.2732G>T p.S911I | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61319786, COSV61327498; called by muse, mutect2, varscan2
- ATP13A4 | c.1187G>T p.R396M | Missense Mutation (SNP) | VAF 114/455 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55075471; called by muse, mutect2, varscan2
- ATP13A4 | c.534-1G>T p.X178_splice | Splice Site (SNP) | VAF 16/380 reads (4%) | catalogued as COSV55066211, COSV99794480; called by muse, mutect2
- ATP1A1 | c.326T>G p.I109S | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV55194351; called by muse, mutect2, varscan2
- ATP1A1 | c.1332+1G>A p.X444_splice | Splice Site (SNP) | VAF 33/121 reads (27%) | catalogued as COSV55194360; called by muse, mutect2, varscan2
- ATP1A2 | c.329T>C p.F110S | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as COSV63406011; called by muse, mutect2
- ATP1A2 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as rs758815329, COSV63406017; called by muse, mutect2, varscan2
- ATP1A4 | c.1880C>A p.P627H | Missense Mutation (SNP) | VAF 69/359 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63628626; called by mutect2, varscan2
- ATP1A4 | c.2510T>C p.I837T | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63628635; called by muse, mutect2, varscan2
- ATP1B1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63179803; called by muse, mutect2
- ATP2B1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1200336674, COSV99665044; called by muse, mutect2, varscan2
- ATP2B1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs868096531, COSV53810259, COSV53813059; called by muse, mutect2, varscan2
- ATP2B2 | c.1166C>T p.A389V (on ENST00000352432; = p.A355V on NM_001683.5) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV59507697; called by muse, mutect2, varscan2
- ATP2B2 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59505994, COSV59507711; called by muse, mutect2, varscan2
- ATP2B3 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV99682648; called by muse, mutect2
- ATP2B4 | c.3088C>A p.L1030M | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.224); catalogued as COSV58177878, COSV58184169; called by muse, varscan2
- ATP4A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs904563816, COSV52871892; called by muse, mutect2, varscan2
- ATP5F1A | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV56359927; called by muse, mutect2
- ATP5MC1 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV63506293; called by muse, mutect2, varscan2
- ATP5PB | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs11553277, COSV71953300; called by muse, mutect2, varscan2
- ATP5PB | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as COSV71953325; called by muse, mutect2, varscan2
- ATP6AP1 | c.1330C>A p.L444M | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63895278; called by muse, mutect2, varscan2
- ATP6V0A2 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV57752353; called by muse, mutect2, varscan2
- ATP6V0E2 | c.133G>A p.A45T (on ENST00000425642; = p.A94T on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs762511980, COSV70416545; called by mutect2, varscan2
- ATP6V1B1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs1553419387, COSV99313717; called by muse, mutect2
- ATP6V1B2 | c.538A>G p.M180V | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as COSV52355352; called by muse, mutect2, varscan2
- ATP6V1D | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV53600752; called by muse, mutect2, varscan2
- ATP6V1F | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV50800291; called by mutect2, varscan2
- ATP6V1F | c.159-1G>T p.X53_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV50800293; called by muse, mutect2, varscan2
- ATP7A | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 138/561 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58454197; called by muse, mutect2, varscan2
- ATP7A | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.542); catalogued as COSV58454862; called by muse, mutect2
- ATP7A | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 54/219 reads (25%) | catalogued as COSV58454211; called by muse, varscan2
- ATP7A | c.3541C>A p.L1181I | Missense Mutation (SNP) | VAF 82/657 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58454227; called by muse, mutect2, varscan2
- ATP7A | c.4169C>A p.S1390Y | Missense Mutation (SNP) | VAF 146/548 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58454244; called by muse, mutect2, varscan2
- ATP8A1 | c.1296C>T p.G432= | Splice Region (SNP) | VAF 34/104 reads (33%) | catalogued as COSV52548727; called by muse, mutect2, varscan2
- ATP8A1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100044568; called by muse, mutect2
- ATP8A2 | c.2820G>A p.M940I | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs1372815705, COSV54977384; called by muse, mutect2, varscan2
- ATP8B1 | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99376674; called by muse, varscan2
- ATP9A | c.905G>A p.C302Y | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58772239; called by muse, varscan2
- ATP9B | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763076944, COSV56956355; called by muse, mutect2, varscan2
- ATR | c.6494C>T p.A2165V | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV63383705; called by muse, mutect2, varscan2
- ATR | c.5171G>T p.R1724M | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63392613; called by muse, mutect2, varscan2
- ATR | c.1041C>A p.C347* | Nonsense Mutation (SNP) | VAF 42/121 reads (35%) | catalogued as COSV63392621; called by muse, mutect2, varscan2
- ATR | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV100637545, COSV63383834; called by muse, mutect2
- ATRIP | c.1139A>T p.N380I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV56498088; called by muse, mutect2, varscan2
- ATRN | c.3643+2T>C p.X1215_splice | Splice Site (SNP) | VAF 14/136 reads (10%) | catalogued as COSV53534708; called by muse, mutect2, varscan2
- ATRNL1 | c.2093G>A p.C698Y | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61817596; called by muse, varscan2
- ATRNL1 | c.2708G>A p.G903D | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.522); catalogued as COSV58116093; called by muse, mutect2, varscan2
- ATRNL1 | c.3761T>C p.I1254T | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV58116103; called by muse, mutect2, varscan2
- ATRX | c.5464G>A p.A1822T | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV64883784; called by muse, mutect2, varscan2
- ATRX | c.2117G>A p.S706N | Missense Mutation (SNP) | VAF 74/576 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.024); catalogued as COSV64883793; called by muse, mutect2, varscan2
- ATXN7 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1157063173, COSV55756823; called by muse, mutect2, varscan2
- ATXN7 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs1369874836, COSV55756867; called by muse, mutect2, varscan2
- ATXN7L2 | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV60206011; called by muse, mutect2, varscan2
- AUH | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.179); catalogued as COSV57866236; called by muse, mutect2, varscan2
- AUP1 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51214381; called by muse, mutect2, varscan2
- AURKB | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs866443565, COSV60244374; called by muse, mutect2, varscan2
- AUTS2 | c.3710C>T p.T1237M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1012077245, COSV61431113; called by muse, mutect2, varscan2
- AVIL | c.1377G>T p.Q459H | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV57683886; called by muse, mutect2, varscan2
- AVPR1A | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1007916577, COSV54547427; called by muse, varscan2
- AWAT2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as COSV52144640; called by muse, mutect2, varscan2
- AXIN2 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs759825875, COSV100195764; ClinVar: uncertain significance; called by muse, mutect2
- AZIN2 | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); catalogued as COSV53860842; called by muse, mutect2, varscan2
- B3GALNT1 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0.058); catalogued as rs1362528658, COSV100251957, COSV57579825; called by muse, mutect2, varscan2
- B3GALNT2 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781198538, COSV58357385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALT1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as rs1425909052, COSV59909879; called by muse, mutect2, varscan2
- B3GNT3 | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57953992; called by muse, mutect2, varscan2
- B3GNT4 | c.69A>T p.G23= | Splice Region (SNP) | VAF 12/20 reads (60%) | catalogued as COSV57337556; called by muse, mutect2, varscan2
- B3GNT4 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57337560; called by muse, varscan2
- B4GALT3 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as rs746359457, COSV60526872; called by muse, mutect2, varscan2
- BAAT | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52291099; called by muse, mutect2, varscan2
- BACH2 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.078); catalogued as rs374812157, COSV57607740; called by mutect2, varscan2
- BAIAP2L2 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.753); catalogued as rs201411605, COSV57637256; called by muse, mutect2, varscan2
- BAK1 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV62349942; called by muse, mutect2, varscan2
- BAP1 | c.1069C>A p.L357M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56240880; called by muse, mutect2, varscan2
- BARD1 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 86/276 reads (31%) | catalogued as COSV53617640; called by mutect2, varscan2
- BARX2 | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55652482; called by muse, mutect2, varscan2
- BAZ1A | c.4033G>A p.A1345T | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV62412233; called by muse, mutect2, varscan2
- BAZ1A | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 65/206 reads (32%) | catalogued as COSV62412236; called by muse, mutect2, varscan2
- BAZ1B | c.2027T>C p.M676T | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as rs782517656, COSV100289459; called by muse, mutect2
- BAZ2A | c.1148G>T p.S383I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV51643946; called by muse, mutect2, varscan2
- BAZ2B | c.4863G>T p.Q1621H | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58610328; called by muse, mutect2, varscan2
- BBOF1 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as rs776896070, COSV63247400; called by muse, mutect2, varscan2
- BBS10 | c.1634C>A p.S545Y | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV101283336, COSV67913304; called by muse, mutect2
- BBS10 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV53889418; called by muse, mutect2, varscan2
- BBS2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV55328698; called by muse, mutect2, varscan2
- BBS7 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV52659636; called by muse, mutect2, varscan2
- BBX | c.1865C>A p.T622N | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57895326; called by muse, mutect2, varscan2
- BCAM | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as rs762226358, COSV54305020; called by muse, mutect2, varscan2
- BCAN | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs200638965, COSV61259724; called by mutect2, varscan2
- BCAN | c.1037G>T p.S346I | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV61259734; called by muse, mutect2, varscan2
- BCAS3 | c.1538G>A p.G513D | Missense Mutation (SNP) | VAF 194/623 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV66780344, COSV66782632; called by muse, mutect2, varscan2
- BCCIP | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV52943502; called by muse, mutect2, varscan2
- BCHE | c.1489A>T p.K497* | Nonsense Mutation (SNP) | VAF 69/212 reads (33%) | catalogued as rs768182433, COSV52262716; called by muse, mutect2, varscan2
- BCKDHB | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV57518948; called by muse, mutect2, varscan2
- BCKDK | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV54894039; called by muse, mutect2, varscan2
- BCKDK | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99570379; called by muse, mutect2
- BCL11A | c.463G>A p.A155T (on ENST00000335712 / NM_001365609.1; = p.A189T on NM_018014.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59625213; called by muse, mutect2, varscan2
- BCL2L14 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs762783178, COSV53794914; called by muse, mutect2, varscan2
- BCL2L2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV51636847; called by muse, mutect2, varscan2
- BCL3 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV51235082; called by muse, mutect2, varscan2
- BCL7C | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53064566; called by muse, mutect2, varscan2
- BCL9 | c.3785A>G p.Q1262R | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.346); catalogued as COSV52350320; called by muse, mutect2, varscan2
- BCL9 | c.4225G>A p.V1409M | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as rs782585337, COSV52349107; called by muse, mutect2, varscan2
- BCL9L | c.2956C>T p.R986C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs535487538, COSV52689361; called by muse, mutect2, varscan2
- BCL9L | c.1502T>C p.M501T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV52689373; called by muse, mutect2, varscan2
- BCO1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs200324875, COSV50734108; called by muse, mutect2, varscan2
- BCOR | c.4540C>T p.R1514* (on ENST00000378444 / NM_001123385.2; = p.R1480* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as CM0910704, COSV60703956, COSV60716852; called by muse, mutect2, varscan2
- BCOR | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV60719068; called by muse, mutect2, varscan2
- BCOR | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV60719083; called by muse, mutect2, varscan2
- BCORL1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs147775035, COSV54390670, COSV99498258; called by muse, mutect2, varscan2
- BCORL1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV99498161; called by muse, mutect2, varscan2
- BCORL1 | c.3398A>G p.Q1133R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as COSV54407471; called by muse, mutect2, varscan2
- BCR | c.2032C>A p.L678I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59935955; called by muse, mutect2, varscan2
- BDKRB1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs573449408, COSV53706364; called by muse, mutect2, varscan2
- BDNF | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59238625; called by muse, mutect2, varscan2
- BDNF | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV59238652; called by muse, mutect2, varscan2
- BDP1 | c.2352G>T p.K784N | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62434950; called by muse, mutect2, varscan2
- BEND3 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs782329383, COSV100944523; called by muse, mutect2
- BEX4 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV65516234; called by muse, mutect2, varscan2
- BHLHE40 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV56576517; called by muse, mutect2, varscan2
- BIRC6 | c.3871C>T p.R1291W | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs763922153, COSV70198081; called by mutect2, varscan2
- BIRC6 | c.14166G>T p.Q4722H | Missense Mutation (SNP) | VAF 143/480 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.979); catalogued as COSV70206346; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57278510; called by muse, mutect2
- BIVM-ERCC5 | c.3688C>A p.L1230M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63247446; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4289C>A p.S1430Y | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV100863556; called by muse, mutect2
- BLID | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.235); catalogued as COSV73340410; called by muse, mutect2, varscan2
- BLMH | c.313del p.W105Gfs*11 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV55587541; called by mutect2, pindel, varscan2
- BLVRB | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV99647807; called by muse, mutect2
- BLZF1 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 82/486 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as COSV61394909; called by mutect2, varscan2
- BMP1 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373883675; called by muse, mutect2, varscan2
- BMP1 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs755773074, COSV60483175; called by mutect2, varscan2
- BMP2 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs201927971, COSV66577064, COSV66578429; called by muse, mutect2, varscan2
- BMP2K | c.1112G>A p.R371K | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58599483; called by muse, mutect2, varscan2
- BMP4 | c.1188T>G p.N396K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417318; called by muse, mutect2, varscan2
- BMP4 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.637); catalogued as COSV55417327; called by muse, mutect2, varscan2
- BMP5 | c.163A>C p.I55L | Missense Mutation (SNP) | VAF 112/399 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63706644; called by muse, mutect2, varscan2
- BMP7 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67782728, COSV67783071; called by muse, mutect2, varscan2
- BMPR2 | c.1467G>T p.E489D | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as CM146778, COSV65813587; called by muse, mutect2
- BMS1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs529159115, COSV65735542; called by muse, mutect2, varscan2
- BMS1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs374294179; called by muse, mutect2, varscan2
- BMS1 | c.3444C>A p.D1148E | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV65735552; called by muse, mutect2, varscan2
- BMS1 | c.3493C>T p.H1165Y | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs752309073, COSV65735557; called by muse, varscan2
- BMT2 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | catalogued as rs1020605621, COSV51774807; called by muse, mutect2, varscan2
- BNC1 | c.2768C>A p.P923H | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs1375916438, COSV100596802; called by muse, mutect2
- BNC2 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as rs763866782, COSV66157782; called by muse, mutect2, varscan2
- BNIP2 | c.178C>A p.L60M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51109432; called by muse, mutect2, varscan2
- BOC | c.1955G>T p.W652L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56358281; called by muse, mutect2, varscan2
- BOC | c.2432-1G>A p.X811_splice | Splice Site (SNP) | VAF 43/194 reads (22%) | catalogued as COSV56358290; called by muse, mutect2, varscan2
- BOD1L1 | c.8908C>T p.R2970C | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs775550481, COSV50068860; called by muse, mutect2, varscan2
- BOD1L1 | c.8110C>A p.L2704I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV50069084; called by muse, mutect2, varscan2
- BOD1L1 | c.7613A>G p.D2538G | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV50056372; called by muse, mutect2, varscan2
- BOD1L1 | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765615103, COSV50069594; called by muse, mutect2, varscan2
- BOD1L1 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV50069738; called by muse, mutect2, varscan2
- BOLA3 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54877549; called by muse, varscan2
- BORA | c.567G>A p.W189* (on ENST00000613797; = p.W114* on NM_024808.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/128 reads (22%) | catalogued as COSV64695928; called by muse, mutect2, varscan2
- BPIFA1 | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 109/410 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs567130205, COSV62825239; called by muse, mutect2, varscan2
- BPIFB2 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50071135; called by mutect2, varscan2
- BPNT1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs923244369, COSV59040324; called by muse, mutect2
- BPTF | c.4766G>T p.R1589M | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV58847254; called by muse, mutect2, varscan2
- BRAF | c.1402T>A p.S468T (on ENST00000288602 / NM_001374244.1; = p.S428T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.709); catalogued as COSV56386580; called by muse, mutect2, varscan2
- BRAF | c.582C>A p.C194* | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | catalogued as COSV56386592; called by muse, mutect2, varscan2
- BRAF | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 138/540 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); catalogued as COSV56237815, COSV56386604; called by muse, mutect2, varscan2
- BRCA1 | c.3539G>T p.S1180I | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV100523122; called by muse, mutect2
9,298 further variants in this file (6,844 protein-altering or splice-affecting, 2,251 silent, 203 other) are not listed here.
